Gene-level copy-number profile of specimen HCM-CSHL-1262-C19-85M from HCMI case HCM-CSHL-1262-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 65.4 years (23,884 days).
Specimen HCM-CSHL-1262-C19-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a200351e-32b4-47a4-9ca1-81e2e183a9e6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-1262-C19-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/a1d52a94-3884-4a3a-a888-795f39dc2814

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 351; copy number 2: 16,839; copy number 3: 32,502; copy number 4: 6,458; copy number 5: 1,247; copy number 6: 1,432; copy number 7: 73.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr4:68,509,441–68,670,652, 6 genes: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 73 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:16,107,878–16,567,490, 1 gene, copy number 7 (within-gene range 6–7): MSR1.
- chr8:16,374,618–20,183,206, 64 genes, copy number 7 (broad region; genes not listed).
- chr8:38,996,754–39,105,445, 1 gene, copy number 7 (within-gene range 2–7): ADAM9.
- chr8:39,106,990–39,522,852, 5 genes, copy number 7: ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A.
- chr14:28,829,881–28,968,400, 1 gene, copy number 7 (within-gene range 3–7): LINC02327.
- chr14:28,901,236–28,901,347, 1 gene, copy number 7: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 346. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
